CCDI case PBCIVE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/3eda97de-8a49-4069-89d5-4f8f3fc24c6e

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 14.7 years (5,364 days).

Biospecimens (4 samples)
- Samples 0DSTY4, 0DSTYJ (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0DSTYA, 0DUHG4 (2 with the same recorded description): Tissue type: Normal; Specimen type: Peripheral Whole Blood.
